Somatic mutation profile of tumor specimen TCGA-66-2763-01A (aliquot TCGA-66-2763-01A-01D-1522-08) from TCGA case TCGA-66-2763, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 63.8 years (23,315 days).
Specimen TCGA-66-2763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cbab038-52d1-4e12-ac47-f79a651f09f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2763-11A (Solid Tissue Normal), aliquot TCGA-66-2763-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e584c371-a387-4bd4-a383-278429cf0e3d

The open-access MAF lists 408 somatic variants for this specimen: 312 protein-altering or splice-affecting, 88 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 268, Silent 88, Nonsense Mutation 26, Splice Site 8, Frame Shift Del 6, Intron 3, Frame Shift Ins 3, RNA 2, 3'UTR 1, Nonstop Mutation 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 143/340 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 31/64 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AASDH | c.889G>T p.G297* | Nonsense Mutation (SNP) | VAF 50/118 reads (42%) | catalogued as COSV52707214; called by muse, varscan2
- ABCA4 | c.4189T>G p.F1397V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs751233838, COSV64674203; called by muse, mutect2, varscan2
- ABCA5 | c.2484A>T p.E828D | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as COSV67017206; called by muse, mutect2, varscan2
- ABCA6 | c.382A>G p.I128V | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as rs1413978747, COSV52639708; called by muse, mutect2, varscan2
- ABCA9 | c.365C>G p.S122* | Nonsense Mutation (SNP) | VAF 139/222 reads (63%) | catalogued as COSV60626044; called by muse, mutect2, varscan2
- ABCB1 | c.2021G>C p.G674A | Missense Mutation (SNP) | VAF 95/320 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV55944671, COSV55953251; called by muse, mutect2, varscan2
- ABCB1 | c.493G>A p.V165M | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as COSV55953260; called by muse, varscan2
- AC008397.2 | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV53207445; called by muse, mutect2, varscan2
- ACSM2A | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54585563; called by muse, mutect2, varscan2
- ADAL | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 94/288 reads (33%) | catalogued as COSV67500655; called by muse, mutect2, varscan2
- ADAM21 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs192946121, COSV50796340; called by muse, mutect2, varscan2
- ADAMTS12 | c.4415G>T p.C1472F | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61264998; called by muse, mutect2, varscan2
- ADCY10 | c.2495G>A p.C832Y | Missense Mutation (SNP) | VAF 114/345 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as COSV63241326; called by muse, mutect2, varscan2
- ADGRG6 | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as COSV51593810; called by muse, mutect2, varscan2
- ADGRG7 | c.1179G>A p.W393* | Nonsense Mutation (SNP) | VAF 26/241 reads (11%) | catalogued as COSV56297473; called by muse, mutect2, varscan2
- ADRA1A | c.362C>A p.S121Y | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52365385; called by muse, mutect2, varscan2
- AGTR2 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 456/628 reads (73%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as COSV64156534, COSV64157083; called by muse, mutect2, varscan2
- AGXT | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56754454; called by muse, varscan2
- AHNAK2 | c.17054C>T p.A5685V | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV60917756; called by muse, mutect2, varscan2
- AHRR | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as rs201569519, COSV57084895; called by muse, mutect2, varscan2
- ALMS1 | c.874C>G p.R292G | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV52511752; called by muse, mutect2, varscan2
- ALMS1 | c.7330C>G p.L2444V | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV52511765; called by muse, mutect2, varscan2
- ANK2 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.359); catalogued as COSV52165593; called by muse, varscan2
- ASIC5 | c.653C>G p.A218G | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV72232852; called by muse, mutect2, varscan2
- ASXL3 | c.3905G>T p.S1302I | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV52468276; called by muse, mutect2, varscan2
- ATP10A | c.3658G>T p.G1220C | Missense Mutation (SNP) | VAF 37/246 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV63518462; called by muse, mutect2, varscan2
- ATP13A3 | c.2638A>G p.M880V | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV55465368; called by muse, mutect2
- ATP2B1 | c.2332A>G p.K778E | Missense Mutation (SNP) | VAF 122/248 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV53808470; called by muse, mutect2, varscan2
- BBS4 | c.59A>T p.K20I | Missense Mutation (SNP) | VAF 41/168 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.054); catalogued as COSV51438310; called by muse, mutect2, varscan2
- BCORL1 | c.2366G>T p.R789L | Missense Mutation (SNP) | VAF 68/113 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54390631, COSV54398067; called by muse, mutect2, varscan2
- BICC1 | c.687G>T p.Q229H | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV54064205; called by muse, mutect2, varscan2
- BICDL1 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV57493587; called by muse, mutect2, varscan2
- BVES | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 153/347 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58948288; called by muse, mutect2, varscan2
- C3 | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as COSV55581643; called by muse, mutect2, varscan2
- C6orf15 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as rs1394387039, COSV52538518; called by muse, mutect2, varscan2
- C7 | c.1601C>G p.S534C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV57475376, COSV57481219; called by muse, mutect2, varscan2
- CACNA1F | c.2152T>A p.Y718N | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59904929; called by muse, mutect2, varscan2
- CALCR | c.599A>T p.H200L (on ENST00000649521 / NM_001164737.2; = p.H184L on NM_001742.4) | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64008803; called by muse, mutect2, varscan2
- CALN1 | c.133T>A p.F45I (on ENST00000329008 / NM_001017440.3; = p.F87I on NM_031468.4) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV61135953; called by muse, mutect2, varscan2
- CAPRIN1 | c.1560C>A p.F520L | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58220230; called by muse, mutect2, varscan2
- CASD1 | c.1667A>T p.K556I | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51973023; called by muse, mutect2, varscan2
- CBLB | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 53/272 reads (19%) | catalogued as rs369966206; called by muse, mutect2, varscan2
- CCAR1 | c.1049G>T p.R350L | Missense Mutation (SNP) | VAF 67/222 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV56266878; called by muse, mutect2, varscan2
- CCDC85A | c.1382C>G p.S461C | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.121); catalogued as COSV68151792, COSV68156554; called by muse, mutect2, varscan2
- CCDC87 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs1267365194, COSV59579317; called by muse, mutect2, varscan2
- CD46 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.315); catalogued as COSV59733827; called by muse, mutect2, varscan2
- CD84 | c.499A>G p.N167D | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs139298884, COSV60868802; called by muse, mutect2, varscan2
- CDAN1 | c.2941A>G p.I981V | Missense Mutation (SNP) | VAF 270/720 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as COSV62332419; called by muse, varscan2
- CDC42BPG | c.3598A>C p.K1200Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61347709; called by muse, mutect2, varscan2
- CES1 | c.1257C>A p.D419E (on ENST00000361503 / NM_001025194.2; = p.D418E on NM_001266.5) | Missense Mutation (SNP) | VAF 86/361 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs139540470, COSV62087397; called by muse, mutect2, varscan2
- CFAP44 | c.2142G>T p.M714I | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV55612169; called by muse, mutect2
- CFAP46 | c.7947G>T p.R2649S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.025); catalogued as COSV54153544, COSV54158979; called by muse, mutect2, varscan2
- CFAP69 | c.771A>T p.L257F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV60186354; called by muse, mutect2, varscan2
- CFHR4 | c.1480G>T p.G494C (on ENST00000367416 / NM_001201551.2; = p.G248C on NM_006684.5) | Missense Mutation (SNP) | VAF 121/662 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52230136; called by muse, mutect2, varscan2
- CLDN10 | c.162C>G p.N54K | Missense Mutation (SNP) | VAF 80/148 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV65297815, COSV65299399; called by muse, mutect2, varscan2
- CLEC12A | c.631T>A p.S211T | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV58561425; called by muse, mutect2, varscan2
- CLEC17A | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60428160; called by muse, mutect2, varscan2
- CLN5 | c.253G>T p.V85F | Missense Mutation (SNP) | VAF 123/231 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as COSV66284300; called by muse, mutect2, varscan2
- CLOCK | c.1895C>T p.S632L | Missense Mutation (SNP) | VAF 70/732 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV59402386; called by muse, mutect2
- CLOCK | c.1709C>G p.S570* | Nonsense Mutation (SNP) | VAF 37/505 reads (7%) | catalogued as COSV59402394; called by muse, mutect2
- CMYA5 | c.11583G>T p.Q3861H | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV69745709; called by muse, mutect2, varscan2
- CNTLN | c.2973G>T p.L991F | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52081465; called by muse, mutect2, varscan2
- CNTN3 | c.1313G>T p.R438M | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV55173760; called by muse, mutect2, varscan2
- CNTNAP2 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV62192126; called by muse, mutect2, varscan2
- CNTNAP2 | c.1664T>C p.I555T | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.053); catalogued as rs780737228, COSV62192132, COSV62267449; called by muse, mutect2, varscan2
- CNTROB | c.2196G>C p.L732F | Missense Mutation (SNP) | VAF 192/376 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as COSV66608374; called by muse, mutect2, varscan2
- COL11A1 | c.3365C>A p.P1122H | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62172782, COSV62185626; called by muse, mutect2, varscan2
- COL12A1 | c.2904G>C p.E968D | Missense Mutation (SNP) | VAF 96/303 reads (32%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.996); catalogued as COSV59397549; called by muse, mutect2, varscan2
- CPNE4 | c.1379C>A p.A460D | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70195155; called by muse, mutect2, varscan2
- CPSF1 | c.133C>G p.R45G | Missense Mutation (SNP) | VAF 189/305 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV52779323; called by muse, mutect2, varscan2
- CRB1 | c.994A>G p.T332A | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.688); catalogued as COSV66342336; called by muse, mutect2, varscan2
- CRYBG2 | c.3511G>T p.V1171L | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.174); catalogued as COSV57486552; called by muse, mutect2, varscan2
- CSMD3 | c.10228A>T p.S3410C (on ENST00000297405 / NM_001363185.1; = p.S3241C on NM_052900.3) | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.838); catalogued as COSV52202283, COSV52320309; called by muse, mutect2, varscan2
- CST11 | c.72C>A p.Y24* | Nonsense Mutation (SNP) | VAF 44/164 reads (27%) | catalogued as COSV63140138; called by muse, mutect2, varscan2
- CWF19L2 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 144/609 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV56513760; called by muse, mutect2, varscan2
- CYP1A1 | c.524A>C p.Q175P | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); catalogued as COSV65697421; called by muse, mutect2, varscan2
- DCSTAMP | c.922G>T p.V308L | Missense Mutation (SNP) | VAF 159/789 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV52577317, COSV52578105; called by muse, mutect2, varscan2
- DDIAS | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 124/791 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV61272364; called by muse, mutect2, varscan2
- DENND2A | c.356del p.G119Dfs*10 | Frame Shift Del (DEL) | VAF 118/453 reads (26%) | catalogued as COSV52052672; called by mutect2, pindel, varscan2
- DENND4B | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57843382; called by muse, mutect2, varscan2
- DIO3 | c.874T>A p.Y292N | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63773841; called by muse, mutect2, varscan2
- DMD | c.10666G>T p.A3556S | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV58916890; called by muse, mutect2, varscan2
- DNAJB1 | c.491T>C p.V164A | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as COSV54317153; called by muse, mutect2, varscan2
- DPEP1 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV55360633; called by muse, mutect2, varscan2
- EBF2 | c.433A>T p.K145* | Nonsense Mutation (SNP) | VAF 8/204 reads (4%) | catalogued as rs960275107, COSV68778336; called by muse, mutect2
- EFCAB6 | c.4225C>A p.H1409N | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV53064957; called by muse, mutect2, varscan2
- EGR2 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV54347189; called by muse, mutect2
- ENTHD1 | c.968C>A p.A323E | Missense Mutation (SNP) | VAF 112/381 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as COSV57321098; called by muse, mutect2, varscan2
- EXO5 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 36/192 reads (19%) | catalogued as COSV56415858, COSV99591198; called by muse, mutect2, varscan2
- EXOSC10 | c.130G>T p.V44L | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV58665820, COSV58668384; called by muse, mutect2, varscan2
- EYA4 | c.811C>G p.P271A | Missense Mutation (SNP) | VAF 78/164 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs752023028, COSV62053553, COSV62060270; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EYA4 | c.1613C>G p.S538C (on ENST00000531901 / NM_001301013.1; = p.S532C on NM_004100.5) | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as COSV100766215, COSV62053567; called by muse, mutect2, varscan2
- FAM13A | c.1721G>C p.W574S | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52004091, COSV52015190; called by muse, varscan2
- FAM149A | c.2249-1G>C p.X750_splice (on ENST00000356371 / NM_001367768.2; = p.X459_splice on NM_015398.3 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 25/77 reads (32%) | catalogued as rs756989427, COSV57027904; called by muse, mutect2
- FAM234B | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1481988179, COSV52195043; called by muse, mutect2, varscan2
- FAM50A | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV50131468; called by muse, mutect2, varscan2
- FAT4 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV67888776; called by muse, mutect2, varscan2
- FBXO22 | c.1100G>T p.R367L | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs141220458, COSV57617752; called by muse, mutect2, varscan2
- FLG2 | c.3022C>A p.Q1008K | Missense Mutation (SNP) | VAF 262/764 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as COSV66169311; called by muse, mutect2, varscan2
- FREM1 | c.3646C>T p.Q1216* | Nonsense Mutation (SNP) | VAF 26/102 reads (25%) | catalogued as COSV101085038, COSV66524892; called by muse, mutect2
- FRYL | c.6554A>G p.Y2185C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51949584; called by muse, mutect2
- FTMT | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV58420507; called by muse, mutect2, varscan2
- GABRR1 | c.1073C>A p.S358* | Nonsense Mutation (SNP) | VAF 27/60 reads (45%) | catalogued as COSV65619614, COSV99055045; called by muse, mutect2, varscan2
- GHRHR | c.1208G>C p.R403T | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs767279880, COSV58196810; called by muse, mutect2, varscan2
- GIMAP1 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV56188443; called by muse, mutect2, varscan2
- GP5 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs759376535, COSV59878665; called by muse, mutect2
- GPR157 | c.179C>G p.S60W | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66233804; called by muse, mutect2
- GRHL3 | c.451G>T p.G151C (on ENST00000350501 / NM_198174.3; = p.G156C on NM_021180.3) | Missense Mutation (SNP) | VAF 126/315 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV52567517; called by muse, mutect2, varscan2
- GRIA2 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52389055, COSV52392928; called by muse, mutect2, varscan2
- GRIA2 | c.2078C>G p.T693S | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52392981; called by muse, mutect2, varscan2
- GRK5 | c.1564A>G p.K522E | Missense Mutation (SNP) | VAF 132/298 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV64866568; called by muse, varscan2
- GRPR | c.959T>A p.F320Y | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV66669591; called by muse, mutect2, varscan2
- GUCY1A1 | c.1550G>T p.C517F | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56652363; called by muse, mutect2, varscan2
- H2AC20 | c.362C>A p.T121N | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV58612190, COSV58612981; called by muse, mutect2, varscan2
- H4C4 | c.233A>T p.K78I | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV61591191; called by muse, mutect2, varscan2
- HELQ | c.2815T>G p.F939V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV55025621, COSV99788186; called by muse, mutect2, varscan2
- HEXA | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD123438, COSV51506910; called by muse, mutect2, varscan2
- HNMT | c.464T>A p.L155Q | Missense Mutation (SNP) | VAF 159/344 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV54508192; called by muse, mutect2, varscan2
- HOXA1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 86/238 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58029958; called by muse, mutect2, varscan2
- HOXD9 | c.215C>G p.S72W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50892160; called by muse, mutect2, varscan2
- HSPA8 | c.1740G>T p.W580C | Missense Mutation (SNP) | VAF 79/277 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV57084260; called by muse, mutect2, varscan2
- HUWE1 | c.12031G>T p.G4011W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53348438; called by muse, mutect2, varscan2
- IFIT1B | c.313T>A p.Y105N | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV65663484; called by muse, mutect2, varscan2
- IGHV1-45 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 96/314 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as rs782800612; called by muse, mutect2, varscan2
- INMT | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); catalogued as COSV50001617; called by muse, mutect2, varscan2
- INSRR | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV63874324; called by muse, mutect2, varscan2
- INTS8 | c.1672A>G p.I558V | Missense Mutation (SNP) | VAF 173/405 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.927); catalogued as COSV58250976; called by muse, mutect2, varscan2
- ITIH6 | c.2080C>A p.P694T | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV54489950; called by muse, mutect2, varscan2
- ITPRID1 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60075965; called by muse, mutect2
- ITPRIPL1 | c.468C>A p.Y156* (on ENST00000439118 / NM_001008949.3; = p.Y164* on NM_178495.6) | Nonsense Mutation (SNP) | VAF 20/181 reads (11%) | catalogued as COSV63153730; called by muse, mutect2, varscan2
- JMJD1C | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 88/235 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.162); catalogued as COSV67862721; called by muse, mutect2, varscan2
- KBTBD3 | c.1700A>C p.D567A | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.999); catalogued as COSV73241458; called by muse, mutect2, varscan2
- KCNN2 | c.1518G>T p.R506S (on ENST00000264773; = p.R718S on NM_021614.4) | Missense Mutation (SNP) | VAF 114/244 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV53290201; called by muse, mutect2, varscan2
- KCTD14 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773238436, COSV62001552; called by muse, mutect2, varscan2
- KIAA1217 | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs569802646, COSV56817736; called by muse, mutect2, varscan2
- KIAA1549 | c.5444G>T p.G1815V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1056618266, COSV54316643; called by muse, mutect2, varscan2
- KIF14 | c.3659C>T p.S1220L | Missense Mutation (SNP) | VAF 56/159 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV66262101; called by muse, mutect2, varscan2
- KIF21A | c.2617G>T p.A873S (on ENST00000361418 / NM_001378440.1; = p.A860S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/217 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746913383, COSV62772539; called by muse, mutect2, varscan2
- KIF26A | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as COSV59467285; called by muse, mutect2, varscan2
- KLHL28 | c.1408A>G p.I470V | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); catalogued as COSV61888393; called by muse, mutect2, varscan2
- KLHL9 | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.602); catalogued as COSV62921742; called by muse, mutect2, varscan2
- KRTAP10-8 | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV58166491; called by muse, mutect2, varscan2
- LIPF | c.1043C>A p.P348H | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1397424838, COSV53284432; called by muse, mutect2, varscan2
- LRFN1 | c.2142C>A p.F714L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV50450481; called by muse, mutect2, varscan2
- LRP1B | c.11834G>T p.G3945V | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as COSV67196683, COSV67230129; called by muse, mutect2, varscan2
- LRRC37A3 | c.3761G>C p.G1254A | Missense Mutation (SNP) | VAF 123/196 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58535613; called by muse, mutect2, varscan2
- LYSMD1 | c.663G>T p.E221D | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64423365; called by muse, mutect2, varscan2
- MAP1B | c.4648G>T p.A1550S | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.955); catalogued as COSV57100457; called by muse, mutect2, varscan2
- MCF2L2 | c.1906A>G p.K636E | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.306); catalogued as COSV61054899; called by muse, mutect2, varscan2
- MCOLN2 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 106/227 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs762235549, COSV52296413; called by muse, mutect2, varscan2
- MKX | c.90C>G p.Y30* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV65392319; called by muse, mutect2
- MS4A14 | c.1939del p.Q647Kfs*31 | Frame Shift Del (DEL) | VAF 51/175 reads (29%) | catalogued as COSV55735349; called by mutect2, pindel, varscan2
- MTR | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs372611712; called by muse, mutect2, varscan2
- MUC16 | c.18767C>A p.T6256N | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as COSV67471814; called by muse, mutect2, varscan2
- MUC5B | c.9808A>T p.T3270S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV71592653; called by muse, varscan2
- MYBBP1A | c.3562G>T p.D1188Y | Missense Mutation (SNP) | VAF 109/215 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV54598491; called by muse, mutect2, varscan2
- MYH6 | c.3841A>T p.K1281* | Nonsense Mutation (SNP) | VAF 63/172 reads (37%) | catalogued as COSV62451521; called by muse, mutect2, varscan2
- MYO18A | c.3800G>C p.R1267P | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV62867799, COSV62870047; called by muse, mutect2, varscan2
- MYO18B | c.5061G>T p.K1687N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV59136684, COSV59145707; called by muse, mutect2, varscan2
- MYO18B | c.5062G>T p.E1688* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV59136690; called by muse, mutect2, varscan2
- MYO3B | c.1265G>T p.C422F | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV100508843, COSV58705520; called by muse, varscan2
- NAV3 | c.3797C>A p.T1266N | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as COSV57084949; called by muse, mutect2, varscan2
- NAV3 | c.4631-1G>T p.X1544_splice | Splice Site (SNP) | VAF 77/183 reads (42%) | catalogued as COSV57084959; called by muse, mutect2, varscan2
- NCAM2 | c.1705G>C p.V569L | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (1); PolyPhen probably damaging (0.985); catalogued as rs761349725, COSV53079918; called by muse, mutect2, varscan2
- NEBL | c.2761+2T>C p.X921_splice | Splice Site (SNP) | VAF 44/177 reads (25%) | catalogued as rs139887121, COSV65803429; called by muse, mutect2, varscan2
- NKTR | c.2677C>T p.R893* | Nonsense Mutation (SNP) | VAF 11/78 reads (14%) | catalogued as rs746276547, COSV51772431; called by muse, mutect2, varscan2
- NLRP11 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV64087407; called by muse, mutect2, varscan2
- NLRP12 | c.3137G>T p.R1046M | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as COSV60748857; called by muse, mutect2, varscan2
- NLRP14 | c.2561T>A p.V854D | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.259); catalogued as COSV55067897; called by muse, mutect2, varscan2
- NNT | c.2851C>T p.L951F | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52925747; called by muse, mutect2
- NOL4L | c.70A>T p.R24W | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV58170144; called by muse, mutect2, varscan2
- NOL8 | c.1906G>T p.A636S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.122); catalogued as COSV62635699; called by muse, mutect2, varscan2
- NOTCH4 | c.1499T>C p.L500P | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV66681289; called by muse, mutect2, varscan2
- NPAT | c.3603A>G p.I1201M | Missense Mutation (SNP) | VAF 365/1087 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV53718569; called by muse, mutect2, varscan2
- NR4A1 | c.884T>A p.V295E | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54483221; called by muse, mutect2, varscan2
- NRK | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 169/254 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV54598408; called by muse, mutect2, varscan2
- NRXN1 | c.2386G>T p.E796* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV58459244, COSV58493099; called by muse, mutect2, varscan2
- NUP210L | c.4702A>T p.T1568S | Missense Mutation (SNP) | VAF 95/322 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV55149400; called by muse, mutect2, varscan2
- NXPE1 | c.834G>T p.R278S (on ENST00000424269; = p.R136S on NM_152315.5) | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV99320705; called by mutect2, varscan2
- OR10R2 | c.737T>C p.L246P | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63768927; called by muse, mutect2, varscan2
- OR14C36 | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV58601560, COSV58602691; called by muse, mutect2, varscan2
- OR2J2 | c.217T>C p.C73R | Missense Mutation (SNP) | VAF 82/408 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV65848078; called by muse, mutect2, varscan2
- OR2T4 | c.46T>A p.F16I | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.049); catalogued as COSV63544177; called by muse, mutect2, varscan2
- OR2T5 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV63540621; called by mutect2, varscan2
- OR4C11 | c.619A>T p.S207C | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV56353063, COSV56353716; called by muse, mutect2, varscan2
- OR4C11 | c.97T>G p.Y33D | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56353725; called by muse, mutect2, varscan2
- OR52B4 | c.192C>A p.F64L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs780185004, COSV68769057; called by muse, mutect2, varscan2
- OTUD4 | c.911A>T p.D304V (on ENST00000447906 / NM_001366057.1; = p.D239V on NM_001102653.1) | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1269288550, COSV71381938, COSV71382265; called by muse, mutect2, varscan2
- OXSR1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs755028275, COSV61259019; called by muse, mutect2, varscan2
- PACRGL | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as COSV54843034; called by muse, mutect2, varscan2
- PALD1 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 18/150 reads (12%) | catalogued as COSV54974576; called by muse, varscan2
- PAPPA2 | c.1558C>G p.R520G | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV62776814, COSV62779600; called by muse, mutect2, varscan2
- PBX1 | c.1109A>T p.Q370L | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs747269460, COSV63344545; called by muse, mutect2, varscan2
- PCDHGB4 | c.2249A>T p.Y750F | Missense Mutation (SNP) | VAF 216/472 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV53963412; called by muse, mutect2, varscan2
- PCMTD1 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 128/230 reads (56%) | catalogued as COSV62122925; called by muse, mutect2, varscan2
- PDE1C | c.851+2T>A p.X284_splice | Splice Site (SNP) | VAF 70/232 reads (30%) | catalogued as COSV58516276; called by muse, mutect2, varscan2
- PDZD2 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56860518; called by muse, varscan2
- PEG10 | c.808C>A p.P270T (on ENST00000482108 / NM_001040152.2; = p.P304T on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV71788341, COSV71788709; called by muse, mutect2
- PELI2 | c.309+1G>T p.X103_splice | Splice Site (SNP) | VAF 71/210 reads (34%) | catalogued as COSV50711767, COSV99953068; called by muse, mutect2, varscan2
- PKHD1 | c.11686C>A p.P3896T | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV64391915; called by muse, mutect2, varscan2
- PLD4 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 43/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66915281; called by muse, mutect2, varscan2
- PLEKHO2 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs776326536, COSV60262213; called by muse, mutect2, varscan2
- PNMA8A | c.1052C>A p.A351D | Missense Mutation (SNP) | VAF 142/576 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV58137379; called by muse, varscan2
- POLD2 | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV56258559; called by muse, mutect2, varscan2
- POLK | c.2504A>G p.Q835R | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV54035926; called by muse, mutect2, varscan2
- POLR3B | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57276226, COSV57279895; called by muse, mutect2, varscan2
- PON1 | c.839T>A p.L280H | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55932339; called by muse, mutect2, varscan2
- PON1 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.031); catalogued as COSV55932351; called by muse, mutect2, varscan2
- PREX2 | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55775722; called by muse, mutect2, varscan2
- PRKCB | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 132/392 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV57776596, COSV57783158; called by muse, mutect2, varscan2
- PRKN | c.1213G>C p.A405P | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV58232341; called by muse, mutect2, varscan2
- PRR23B | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.583); catalogued as COSV61494052; called by muse, mutect2, varscan2
- PSKH1 | c.848T>G p.L283R | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52123727, COSV99344542; called by muse, mutect2, varscan2
- PXDNL | c.2864T>A p.L955Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62485619; called by muse, mutect2, varscan2
- RAB40A | c.47A>T p.K16M | Missense Mutation (SNP) | VAF 183/235 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58491402; called by muse, mutect2, varscan2
- RCAN1 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.932); catalogued as COSV58250262; called by muse, mutect2, varscan2
- RELN | c.4121T>A p.V1374D | Missense Mutation (SNP) | VAF 112/410 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.945); catalogued as COSV59007466; called by muse, mutect2, varscan2
- RGS8 | c.482G>T p.R161M (on ENST00000367556 / NM_001369564.2; = p.R179M on NM_033345.3) | Missense Mutation (SNP) | VAF 130/406 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51116999; called by muse, mutect2, varscan2
- RIN3 | c.2615C>A p.S872Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV53650005; called by muse, mutect2, varscan2
- RINT1 | c.2345A>T p.N782I | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV57558915; called by muse, mutect2, varscan2
- ROBO2 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV59915004, COSV59917995; called by muse, varscan2
- ROR2 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65219835; called by muse, mutect2, varscan2
- RP1 | c.5147G>T p.G1716V | Missense Mutation (SNP) | VAF 66/353 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.153); catalogued as COSV55118507; called by muse, mutect2, varscan2
- RUNX1T1 | c.1372C>T p.R458C (on ENST00000265814 / NM_001198628.1; = p.R431C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1381105316, COSV56138759; called by muse, mutect2, varscan2
- S1PR1 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59513445; called by muse, mutect2, varscan2
- SART1 | c.1661A>T p.N554I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56712030; called by muse, mutect2, varscan2
- SCARF1 | c.2333G>T p.R778L | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV53959129, COSV53960134; called by muse, mutect2, varscan2
- SCML2 | c.883C>G p.P295A | Missense Mutation (SNP) | VAF 74/373 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV52621873; called by muse, mutect2, varscan2
- SCN1A | c.1712G>T p.R571I | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV57662076, COSV57672659; called by muse, mutect2, varscan2
- SENP1 | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV50291237; called by muse, mutect2, varscan2
- SF1 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs763865200, COSV57114449; called by muse, mutect2, varscan2
- SFMBT2 | c.2197A>G p.S733G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV62810774; called by muse, mutect2
- SGPP1 | c.775-1G>A p.X259_splice | Splice Site (SNP) | VAF 25/79 reads (32%) | catalogued as COSV99905915; called by muse, mutect2, varscan2
- SIGLEC12 | c.1692G>T p.Q564H (on ENST00000291707 / NM_053003.4; = p.Q446H on NM_033329.2) | Missense Mutation (SNP) | VAF 69/241 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52462138; called by muse, mutect2, varscan2
- SLC22A12 | c.578C>A p.A193D | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV60572478; called by muse, mutect2, varscan2
- SLC24A4 | c.1745G>T p.R582L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.61); catalogued as COSV54114245; called by muse, mutect2, varscan2
- SLC35F2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.204); catalogued as COSV56183616; called by muse, mutect2, varscan2
- SLC6A14 | c.1038T>A p.D346E | Missense Mutation (SNP) | VAF 362/541 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64147334; called by muse, mutect2, varscan2
- SNX24 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV54452093; called by muse, mutect2, varscan2
- SORCS3 | c.1351C>A p.Q451K | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV63812621; called by muse, mutect2, varscan2
- SPAM1 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 108/304 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs748725260, COSV56144485, COSV56146996; called by muse, mutect2, varscan2
- SPATA19 | c.119A>G p.H40R | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54483595; called by muse, mutect2, varscan2
- SPATA31D1 | c.4363C>G p.Q1455E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.702); catalogued as COSV61196738; called by muse, mutect2, varscan2
- SPEF2 | c.3064-1G>T p.X1022_splice | Splice Site (SNP) | VAF 20/133 reads (15%) | catalogued as COSV61548962; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3160G>C p.D1054H | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59131752; called by muse, mutect2, varscan2
- STYK1 | c.96G>T p.L32F | Missense Mutation (SNP) | VAF 86/364 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV50013456; called by muse, mutect2, varscan2
- SYCP2L | c.171A>T p.K57N | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51653966; called by muse, mutect2, varscan2
- SYT11 | c.427G>T p.E143* | Nonsense Mutation (SNP) | VAF 85/282 reads (30%) | catalogued as COSV64174084, COSV64174744; called by muse, mutect2, varscan2
- SYTL2 | c.1606G>T p.A536S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV60359839; called by muse, mutect2, varscan2
- TAAR5 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as rs1321627353, COSV57799186; called by muse, varscan2
- TBC1D25 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.601); catalogued as COSV65123891; called by muse, varscan2
- TET1 | c.1551A>C p.L517F | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV65385448; called by muse, mutect2, varscan2
- TET1 | c.6358G>T p.V2120L | Missense Mutation (SNP) | VAF 108/332 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV65381772, COSV65385455; called by muse, mutect2, varscan2
- THADA | c.4433A>T p.Q1478L | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV57685412; called by muse, mutect2, varscan2
- THEMIS | c.1615C>A p.Q539K | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.162); catalogued as COSV64071660; called by muse, mutect2, varscan2
- TIPARP | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 67/383 reads (17%) | catalogued as COSV55814415; called by muse, mutect2, varscan2
- TLL2 | c.1759G>T p.G587W | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63570541, COSV63572986; called by muse, mutect2, varscan2
- TMEM222 | c.194+1G>T p.X65_splice | Splice Site (SNP) | VAF 6/12 reads (50%) | catalogued as COSV65027174; called by muse, varscan2
- TMEM39A | c.1416A>T p.L472F | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59900616; called by muse, mutect2, varscan2
- TMIGD1 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61028699; called by muse, mutect2, varscan2
- TMPRSS7 | c.1447C>T p.P483S (on ENST00000452346; = p.P357S on NM_001042575.2) | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757002153, COSV69981039; called by muse, mutect2
- TNN | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs749585837, COSV53427335; called by muse, mutect2, varscan2
- TRA2B | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52025568; called by muse, mutect2, varscan2
- TREML4 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV58385315; called by muse, mutect2, varscan2
- TRIM42 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53883685; called by muse, mutect2, varscan2
- TRIM72 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV59068159; called by muse, mutect2, varscan2
- TRMT2B | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 267/350 reads (76%) | SIFT deleterious (0.05); PolyPhen benign (0.224); catalogued as COSV58619792; called by muse, mutect2, varscan2
- TSGA10IP | c.1032G>C p.L344F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV73245312; called by muse, mutect2, varscan2
- TTN | c.33407del p.P11136Lfs*29 (on ENST00000591111; = p.P10209Lfs*29 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as COSV100596568; called by mutect2, pindel, varscan2
- TTPA | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.268); catalogued as COSV52646893; called by muse, mutect2, varscan2
- TULP1 | c.1081del p.R361Efs*10 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | catalogued as CM140477, COSV57693341; called by mutect2, pindel, varscan2
- TXLNG | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 41/175 reads (23%) | catalogued as COSV58113055; called by muse, mutect2, varscan2
- U2SURP | c.3089G>C p.*1030Sext*73 | Nonstop Mutation (SNP) | VAF 31/75 reads (41%) | catalogued as COSV67531362; called by muse, mutect2, varscan2
- UGT2A3 | c.756G>C p.E252D | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.057); catalogued as COSV52360463; called by muse, mutect2, varscan2
- UNC5D | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV54800873; called by muse, mutect2
- USP11 | c.1533G>T p.Q511H (on ENST00000218348; = p.Q468H on NM_001371072.1) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54474033; called by muse, mutect2, varscan2
- USP24 | c.5185G>A p.D1729N | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV53769421; called by muse, mutect2, varscan2
- USP9X | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as COSV61069973; called by muse, mutect2, varscan2
- VCX3A | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 104/896 reads (12%) | catalogued as COSV66910696; called by muse, varscan2
- WDR26 | c.1325A>T p.Q442L (on ENST00000414423 / NM_001379403.1; = p.Q342L on NM_025160.7) | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV54356126; called by muse, mutect2, varscan2
- WDR33 | c.3274G>T p.E1092* | Nonsense Mutation (SNP) | VAF 113/420 reads (27%) | catalogued as COSV59249947, COSV59252702; called by muse, mutect2, varscan2
- WDR72 | c.1995T>G p.F665L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.556); catalogued as COSV64748154; called by muse, mutect2, varscan2
- WNK3 | c.3746G>A p.G1249E | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100671707; called by muse, mutect2, varscan2
- WNT10B | c.1069C>G p.R357G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV56405562; called by muse, mutect2, varscan2
- XKR7 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs984731810, COSV73813198; called by muse, mutect2, varscan2
- YTHDC2 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as COSV50742354; called by muse, mutect2, varscan2
- ZBTB46 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55510911; called by muse, mutect2
- ZFAND6 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1394761608, COSV55712165; called by muse, mutect2, varscan2
- ZFP64 | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53800149; called by muse, mutect2, varscan2
- ZIC1 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51554248; called by muse, mutect2, varscan2
- ZNF318 | c.4234G>A p.G1412R | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58933316; called by muse, mutect2, varscan2
- ZNF320 | c.1299G>T p.R433S | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV67088281; called by muse, mutect2, varscan2
- ZNF324B | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV60742154; called by muse, mutect2, varscan2
- ZNF480 | c.1370G>T p.C457F | Missense Mutation (SNP) | VAF 95/328 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57996587; called by muse, mutect2, varscan2
- ZNF527 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 150/414 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV62231158; called by muse, mutect2, varscan2
- ZNF583 | c.82A>T p.R28W | Missense Mutation (SNP) | VAF 65/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52402912; called by muse, mutect2, varscan2
- ZNF665 | c.1502G>T p.G501V (on ENST00000600412; = p.G566V on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/355 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV67215556; called by muse, mutect2, varscan2
- ZNF783 | c.585A>G p.I195M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV65185614; called by muse, mutect2, varscan2
- ZNF804B | c.988C>G p.H330D | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV60831186, COSV60832295; called by muse, mutect2, varscan2
- CDH19 | c.411dup p.V138Sfs*6 | Frame Shift Ins (INS) | VAF 72/168 reads (43%) | called by mutect2, varscan2
- CPZ | c.1017_1018insA p.G340Rfs*17 (on ENST00000360986 / NM_001014447.3; = p.G329Rfs*17 on NM_003652.3) | Frame Shift Ins (INS) | VAF 15/55 reads (27%) | called by mutect2, pindel*
- FAM117A | c.331del p.A111Pfs*20 | Frame Shift Del (DEL) | VAF 30/65 reads (46%) | called by mutect2, pindel, varscan2
- IGHG3 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV2-18 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 133/424 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- KMT2D | c.2760dup p.G921Wfs*48 | Frame Shift Ins (INS) | VAF 45/137 reads (33%) | called by mutect2, pindel, varscan2
- POTED | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.011); called by mutect2, varscan2
- TRAV22 | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TRAV29DV5 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- TRDV2 | c.251A>T p.Q84L | Missense Mutation (SNP) | VAF 91/245 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- TTN | c.82935del p.A27646Pfs*114 (on ENST00000591111; = p.A20222Pfs*114 on NM_003319.4) | Frame Shift Del (DEL) | VAF 97/247 reads (39%) | called by mutect2, pindel, varscan2
- ABCA1 | c.5409G>T p.L1803= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as COSV66066929; called by muse, mutect2, varscan2
- ADAMTS9 | c.2118A>T p.I706= | Silent (SNP) | VAF 63/142 reads (44%) | catalogued as COSV55782831; called by muse, mutect2, varscan2
- ADRA1A | c.363C>A p.S121= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV52365324; called by muse, mutect2, varscan2
- AKAP13 | c.1170C>T p.D390= | Silent (SNP) | VAF 20/246 reads (8%) | catalogued as COSV63460645; called by muse, mutect2
- APMAP | c.633G>A p.K211= | Silent (SNP) | VAF 110/378 reads (29%) | catalogued as COSV54174340; called by muse, varscan2
- ARHGEF15 | c.1785C>A p.I595= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV62724633, COSV62725454; called by muse, mutect2, varscan2
- B3GAT1 | c.477C>T p.R159= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1247871633, COSV56998007; called by muse, mutect2
- BDH1 | c.447G>T p.T149= | Silent (SNP) | VAF 122/276 reads (44%) | catalogued as rs374123564; called by muse, mutect2
- C10orf90 | c.1893G>C p.L631= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as COSV52949081, COSV52956733; called by muse, mutect2, varscan2
- CACNA1F | c.4992G>T p.T1664= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as COSV59904924; called by muse, mutect2, varscan2
- CAPN6 | c.1719C>T p.T573= | Silent (SNP) | VAF 74/822 reads (9%) | catalogued as rs751638806, COSV60695334; called by muse, mutect2
- CARMIL1 | c.537A>G p.Q179= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs1405218344, COSV61518702; called by muse, varscan2
- CASK | c.2550T>C p.F850= (on ENST00000378163 / NM_001367721.1; = p.F845= on NM_003688.3) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV59367953; called by muse, mutect2, varscan2
- CEP170 | c.3255A>G p.S1085= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as rs1558468396, COSV60509975; called by muse, mutect2, varscan2
- CHRD | c.2766G>C p.S922= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs549612778; called by mutect2, varscan2
- CNTN3 | c.1407G>C p.V469= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as COSV55173748; called by muse, mutect2, varscan2
- COL18A1 | c.5229C>G p.L1743= (on ENST00000359759 / NM_130444.3; = p.L1508= on NM_030582.4) | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as rs1171902353, COSV60589555; called by muse, mutect2, varscan2
- CSMD3 | c.8634T>A p.P2878= (on ENST00000297405 / NM_001363185.1; = p.P2709= on NM_052900.3) | Silent (SNP) | VAF 45/203 reads (22%) | catalogued as COSV52202300; called by muse, mutect2, varscan2
- CTSC | c.780A>C p.S260= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as COSV57058305; called by muse, mutect2, varscan2
- DGKK | c.3540C>A p.A1180= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1023803651, COSV65707839; called by muse, mutect2, varscan2
- DIO2 | c.426C>A p.A142= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV70445196, COSV70445273; called by muse, mutect2, varscan2
- DQX1 | c.1587G>C p.L529= | Silent (SNP) | VAF 84/344 reads (24%) | catalogued as COSV52046186; called by muse, mutect2, varscan2
- DSC2 | c.912C>A p.I304= | Silent (SNP) | VAF 97/220 reads (44%) | catalogued as COSV51865657, COSV99199896; called by muse, mutect2, varscan2
- EGFR | c.1707C>T p.I569= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as COSV51807289; called by muse, mutect2, varscan2
- EHHADH | c.213A>G p.T71= | Silent (SNP) | VAF 78/135 reads (58%) | catalogued as COSV51630708; called by muse, mutect2, varscan2
- FAM126A | c.1479C>T p.Y493= | Silent (SNP) | VAF 100/302 reads (33%) | catalogued as rs759045816, COSV69472027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM78B | c.333C>T p.S111= | Silent (SNP) | VAF 28/187 reads (15%) | catalogued as COSV57978107; called by muse, mutect2, varscan2
- FCER1A | c.486C>T p.S162= | Silent (SNP) | VAF 50/175 reads (29%) | catalogued as COSV63667046; called by muse, mutect2, varscan2
- FLCN | c.345C>G p.P115= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV53259909; called by muse, mutect2, varscan2
- FLYWCH1 | c.960A>G p.G320= (on ENST00000253928 / NM_001308068.2; = p.G319= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV54146656; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.138T>C p.R46= | Silent (SNP) | VAF 55/172 reads (32%) | catalogued as COSV63041908; called by muse, mutect2, varscan2
- FSCB | c.30A>G p.V10= | Silent (SNP) | VAF 189/610 reads (31%) | catalogued as COSV61218368; called by muse, mutect2, varscan2
- FUT8 | c.531T>A p.G177= (on ENST00000360689 / NM_001371534.1; = p.G14= on NM_004480.4) | Silent (SNP) | VAF 72/286 reads (25%) | catalogued as COSV61285586; called by muse, mutect2, varscan2
- GALC | c.429T>C p.N143= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV54326249; called by muse, mutect2, varscan2
- GDI2 | c.259C>T p.L87= | Silent (SNP) | VAF 66/190 reads (35%) | catalogued as COSV66335026; called by muse, mutect2, varscan2
- GNL3L | c.510G>T p.L170= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV60576685; called by muse, mutect2, varscan2
- GPR22 | c.990T>A p.S330= | Silent (SNP) | VAF 67/208 reads (32%) | catalogued as COSV51753380; called by muse, mutect2, varscan2
- GRB10 | c.1239G>A p.R413= (on ENST00000398812; = p.R367= on NM_001001549.3) | Silent (SNP) | VAF 42/186 reads (23%) | catalogued as COSV60011365; called by muse, mutect2, varscan2
- GRIA2 | c.1779G>T p.G593= | Silent (SNP) | VAF 67/205 reads (33%) | catalogued as COSV52390550, COSV52392955; called by muse, mutect2, varscan2
- GTPBP3 | c.693G>T p.V231= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV50180145; called by muse, mutect2, varscan2
- HLA-DQA1 | c.219G>A p.E73= | Silent (SNP) | VAF 42/123 reads (34%) | catalogued as COSV58239533; called by muse, mutect2, varscan2
- ITGA7 | c.2787C>T p.G929= (on ENST00000555728; = p.G885= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs751647692, COSV57695965, COSV57697621; called by muse, mutect2, varscan2
- ITGAV | c.1797T>A p.A599= | Silent (SNP) | VAF 75/179 reads (42%) | catalogued as COSV53713730; called by muse, mutect2, varscan2
- KLHL34 | c.1218G>T p.T406= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV65279547; called by muse, mutect2
- KLK13 | c.276G>T p.G92= | Silent (SNP) | VAF 78/214 reads (36%) | catalogued as COSV50067132; called by muse, mutect2, varscan2
- LCT | c.1086C>A p.I362= | Silent (SNP) | VAF 73/147 reads (50%) | catalogued as COSV51550983; called by muse, mutect2, varscan2
- LRRTM1 | c.1170G>T p.S390= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs200884012, COSV54439806, COSV54442685; called by muse, mutect2, varscan2
- MS4A8 | c.630C>A p.V210= | Silent (SNP) | VAF 122/304 reads (40%) | catalogued as COSV55754647; called by muse, mutect2, varscan2
- MUC16 | c.29349T>A p.S9783= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV67471806; called by muse, mutect2, varscan2
- MYO18B | c.6030G>A p.A2010= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs748527777, COSV59136698; called by muse, mutect2
- NLRP2 | c.829C>T p.L277= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as COSV54754584; called by muse, mutect2, varscan2
- OR2L3 | c.81C>T p.F27= | Silent (SNP) | VAF 247/856 reads (29%) | catalogued as rs1263475318, COSV63455372; called by muse, mutect2, varscan2
- OR2M7 | c.237C>A p.P79= | Silent (SNP) | VAF 204/638 reads (32%) | catalogued as COSV58739371; called by muse, mutect2, varscan2
- OR51S1 | c.933C>G p.L311= | Silent (SNP) | VAF 61/136 reads (45%) | catalogued as COSV59058746; called by muse, mutect2, varscan2
- OSBPL3 | c.2031T>C p.F677= | Silent (SNP) | VAF 74/222 reads (33%) | catalogued as rs1176015936, COSV57657554; called by muse, mutect2, varscan2
- PALD1 | c.492G>T p.R164= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as COSV54974564; called by muse, varscan2
- PCDH1 | c.402G>A p.L134= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as rs746401175, COSV54614760; called by muse, mutect2, varscan2
- PCDH10 | c.2013C>A p.T671= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV52096023, COSV99992934; called by muse, mutect2, varscan2
- PCDHGB2 | c.2137C>T p.L713= | Silent (SNP) | VAF 68/179 reads (38%) | catalogued as COSV53963402; called by muse, mutect2, varscan2
- PGBD2 | c.1150C>T p.L384= | Silent (SNP) | VAF 59/183 reads (32%) | catalogued as COSV61400367; called by muse, mutect2, varscan2
- PIWIL2 | c.234G>A p.L78= | Silent (SNP) | VAF 73/154 reads (47%) | catalogued as COSV63251998; called by muse, mutect2, varscan2
- PKHD1 | c.3621C>A p.S1207= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV61879722; called by muse, mutect2, varscan2
- PLXNA2 | c.297C>A p.I99= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as COSV65441427; called by muse, mutect2, varscan2
- POP1 | c.1302G>C p.L434= | Silent (SNP) | VAF 114/499 reads (23%) | catalogued as COSV62893054; called by muse, mutect2, varscan2
- PRSS12 | c.1677A>G p.K559= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV56606933; called by muse, mutect2, varscan2
- PTCD1 | c.1530C>G p.L510= | Silent (SNP) | VAF 64/184 reads (35%) | catalogued as COSV52864248; called by muse, mutect2, varscan2
- PTGDR | c.663C>T p.A221= | Silent (SNP) | VAF 31/113 reads (27%) | catalogued as COSV60094178; called by muse, mutect2, varscan2
- PXDNL | c.3411G>A p.S1137= | Silent (SNP) | VAF 29/307 reads (9%) | catalogued as COSV100686303, COSV62489353; called by muse, mutect2, varscan2
- RINL | c.855C>T p.I285= (on ENST00000591812 / NM_001195833.2; = p.I171= on NM_198445.4) | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV61574916; called by muse, mutect2, varscan2
- SETDB1 | c.99G>T p.L33= | Silent (SNP) | VAF 118/329 reads (36%) | catalogued as COSV54984525; called by muse, mutect2, varscan2
- SIGLECL1 | c.135C>A p.P45= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as COSV57063214, COSV57064647; called by muse, mutect2, varscan2
- SLC25A11 | c.12G>T p.T4= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV52591186; called by muse, mutect2, varscan2
- SLC5A11 | c.639A>T p.I213= | Silent (SNP) | VAF 182/531 reads (34%) | catalogued as COSV61741987; called by muse, mutect2, varscan2
- SLITRK1 | c.1446G>T p.L482= | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as rs1228290125, COSV65676102; called by muse, mutect2, varscan2
- TAS2R1 | c.696C>A p.S232= | Silent (SNP) | VAF 36/116 reads (31%) | catalogued as COSV66778783; called by muse, mutect2, varscan2
- TATDN3 | c.123A>C p.A41= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV65325383; called by muse, mutect2, varscan2
- TBC1D22B | c.1278G>A p.L426= | Silent (SNP) | VAF 72/243 reads (30%) | catalogued as COSV65142866; called by muse, mutect2, varscan2
- TBX2 | c.1449G>A p.L483= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1423828573, COSV53598514, COSV99539007; called by muse, mutect2, varscan2
- TMEM131L | c.828C>T p.N276= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV53645413; called by muse, mutect2, varscan2
- TPO | c.1695T>C p.F565= | Silent (SNP) | VAF 61/186 reads (33%) | catalogued as rs756738202, COSV61103337; called by muse, mutect2, varscan2
- TRAF2 | c.414G>T p.A138= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV56038417; called by muse, mutect2, varscan2
- TRAF4 | c.1209C>T p.H403= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs777845875, COSV52218575; called by muse, mutect2, varscan2
- TRIM47 | c.1557C>T p.S519= | Silent (SNP) | VAF 106/168 reads (63%) | catalogued as COSV54668572; called by muse, mutect2, varscan2
- UNC13C | c.4638A>T p.V1546= | Silent (SNP) | VAF 49/252 reads (19%) | catalogued as COSV52881912; called by muse, mutect2, varscan2
- WNK3 | c.1500T>A p.A500= | Silent (SNP) | VAF 27/141 reads (19%) | catalogued as COSV63614470; called by muse, mutect2, varscan2
- ZCWPW2 | c.312A>T p.V104= | Silent (SNP) | VAF 144/292 reads (49%) | catalogued as COSV67499353; called by muse, mutect2, varscan2
- ZFYVE26 | c.5769G>T p.R1923= | Silent (SNP) | VAF 75/269 reads (28%) | catalogued as COSV61329451; called by muse, mutect2, varscan2
- ZIC1 | c.411C>A p.A137= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV51552643, COSV51554266; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852006 C>A | 3'Flank (SNP) | VAF 18/42 reads (43%) | catalogued as rs761377063; called by muse, mutect2, varscan2
- ANK1 | c.5619+263G>T | Intron (SNP) | VAF 72/339 reads (21%) | catalogued as COSV99226045; called by muse, mutect2, varscan2
- C8orf44-SGK3 | c.-481-1813C>T | Intron (SNP) | VAF 6/24 reads (25%) | catalogued as COSV66402372; called by muse, mutect2, varscan2
- COL11A1 | c.898-277del | Intron (DEL) | VAF 67/206 reads (33%) | catalogued as COSV62196478; called by pindel, varscan2
- MFRP | chr11:119345849 del G | 5'Flank (DEL) | VAF 46/153 reads (30%) | called by mutect2, varscan2
- SLC22A17 | n.1019C>T | RNA (SNP) | VAF 105/237 reads (44%) | catalogued as rs1188927988, COSV52835878; called by muse, mutect2, varscan2
- TUBB7P | n.476A>T | RNA (SNP) | VAF 45/105 reads (43%) | called by muse, mutect2, varscan2
- ZNF804A | c.*2C>A | 3'UTR (SNP) | VAF 210/442 reads (48%) | catalogued as COSV100169004; called by muse, mutect2, varscan2
